CCDI case PBCPMN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/8cc946c8-f3ec-49cb-a8ab-cd1437232a9d

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Undifferentiated sarcoma: ICD-O-3 morphology code: 8805/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 16.1 years (5,866 days).

Biospecimens (3 samples)
- Sample 0DWVEL: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DWVEZ, 0DWVGP (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
